Gene-level copy-number profile of tumor specimen ALCH-B46A-TTP1-A from ALCHEMIST case ALCH-B46A, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.6 years (21,777 days).
Specimen ALCH-B46A-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7826b838-b6e3-4aa4-904e-1357d68232f0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B46A-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/90f933e3-5c82-4182-8d03-58a9336b7693

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 8,622; copy number 2: 49,147; copy number 3: 505; copy number 4: 62; copy number 5: 6; copy number 7: 2.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,938,472–13,032,130, 2 genes (within-gene range 0–1): PRAMEF6, PRAMEF28P.
- chr1:13,060,869–13,062,229, 1 gene (within-gene range 0–1): HNRNPCL3.
- chr2:90,359,809–91,621,421, 5 genes (within-gene range 0–2): AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1.
- chr3:129,591,349–129,591,635, 1 gene (within-gene range 0–2): RN7SL752P.
- chr4:49,523,648–49,524,185, 2 genes: AC119751.2, AC119751.8.
- chr8:43,542,076–43,544,057, 1 gene: AC134698.2.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr14:105,467,793–105,470,617, 1 gene (within-gene range 0–2): AL928654.2.
- chr15:25,180,497–25,225,284, 25 genes (within-gene range 0–2): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:25,239,838–25,239,919, 1 gene (within-gene range 0–2): SNORD115-38.
- chr17:2,688,473–2,688,960, 1 gene: AC005696.3.
- chr22:38,426,327–38,455,199, 2 genes (within-gene range 0–1): KCNJ4, Z97056.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,991,134–8,026,309, 2 genes, copy number 5: AL034417.4, ERRFI1.
- chr14:105,647,924–105,649,057, 1 gene, copy number 7: COPDA1.
- chr19:1,103,926–1,174,268, 2 genes, copy number 5: GPX4, SBNO2.
- chr19:1,228,287–1,244,825, 3 genes, copy number 5–7 (within-gene range 4–7): CBARP, AC004221.1, ATP5F1D.

Autosomal genes at a single copy (total copy number 1): 8,177. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
